Somatic mutation profile of tumor specimen TCGA-DX-A3UC-01A (aliquot TCGA-DX-A3UC-01A-11D-A307-09) from TCGA case TCGA-DX-A3UC, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 37.6 years (13,745 days).
Specimen TCGA-DX-A3UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00b4b077-cf63-4b0f-9aeb-7b7dc1b8f8ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UC-10A (Blood Derived Normal), aliquot TCGA-DX-A3UC-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16004c01-0796-4d4d-8082-31025f2a319c

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPH | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100727662; called by muse, mutect2, varscan2
- CHRDL2 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.078); catalogued as rs769845087, COSV99733919; called by muse, mutect2, varscan2
- CYP4F2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99171098; called by muse, mutect2, varscan2
- DICER1 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as rs1060503630, COSV58622315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L4A | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99813656; called by muse, mutect2, varscan2
- FREM2 | c.2289G>C p.L763F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99749516; called by muse, mutect2
- LAMA4 | c.3347G>T p.S1116I (on ENST00000230538 / NM_001105206.3; = p.S1109I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100038813; called by muse, mutect2, varscan2
- LAYN | c.421G>T p.D141Y (on ENST00000375615 / NM_001258390.1; = p.D133Y on NM_178834.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986250; called by mutect2, varscan2
- MROH2B | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV101270790; called by muse, mutect2, varscan2
- OTOGL | c.2510C>T p.P837L (on ENST00000547103; = p.P828L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV72008008; called by muse, mutect2, varscan2
- PHAX | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99881559; called by muse, mutect2
- PHLPP2 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as COSV100673756; called by muse, mutect2, varscan2
- PTCHD1 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV101037828; called by muse, mutect2, varscan2
- SLX4 | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs1024580926, COSV53567159; called by muse, mutect2, varscan2
- SREBF2 | c.1822C>A p.L608M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100761473, COSV63330406; called by muse, mutect2, varscan2
- TMCO6 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99347242; called by muse, mutect2, varscan2
- TTLL2 | c.1212G>C p.K404N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514831; called by muse, mutect2, varscan2
- VPS16 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs769404930, COSV100988430; called by mutect2, varscan2
- WRAP53 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99420316; called by muse, mutect2, varscan2
- ZNF462 | c.3812C>T p.S1271L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52934758; called by muse, mutect2, varscan2
- ZNF644 | c.902C>G p.T301S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV100494566; called by muse, mutect2, varscan2
- PRAMEF10 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- APOB | c.11244G>A p.T3748= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as rs72654406, COSV99266489; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ETV3L | c.852A>G p.P284= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs770948021, COSV101485601; called by muse, mutect2, varscan2
- MAP3K21 | c.2793C>T p.V931= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100786122; called by muse, mutect2, varscan2
- PRMT2 | c.1158A>T p.G386= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99388744; called by muse, varscan2
- TGM4 | c.756C>A p.I252= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99942476; called by muse, mutect2, varscan2
